CCDI case PBCWRE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/db9d863c-0432-4e80-b577-05606d736f52

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1NYU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1O0I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E1O0V: Tissue type: Tumor; Specimen type: Solid Tissue.
